Gene-level copy-number profile of tumor specimen TCGA-51-4081-01A from TCGA case TCGA-51-4081, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.5 years (20,261 days).
Specimen TCGA-51-4081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2b6dfa85-00a3-4911-998c-caf9fd413ad4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-51-4081-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3dd0b4e-d275-483a-9d4b-34b2a54e8077

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 434; copy number 2: 14,755; copy number 3: 10,189; copy number 4: 26,986; copy number 5: 2,858; copy number 6: 2,698; copy number 7: 1,785.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-51-4081-01A-01D-1097-01): tumor purity 0.63, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,529,251, 2 genes: AC008833.1, NDUFB4P2.
- chr5:163,039,291–163,039,599, 1 gene: MRPL57P6.
- chr9:20,658,309–24,592,104, 77 genes (broad region; genes not listed).
- chr9:26,642,697–27,944,497, 26 genes: AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
